Gene-level copy-number profile of tumor specimen C3N-02283-02 from CPTAC case C3N-02283, project CPTAC-3 (Bronchus and lung — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: GX; Age at diagnosis: 67.3 years (24,583 days).
Specimen C3N-02283-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 7f15c654-6844-4487-9f35-9667229089da.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-02283-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,731 have no estimate.
https://portal.gdc.cancer.gov/files/404ce58a-1597-44bf-9a5e-9d4797b3e0fe

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 512; copy number 1: 1,844; copy number 2: 14,530; copy number 3: 26,662; copy number 4: 8,281; copy number 5: 4,088; copy number 6: 1,349; copy number 7: 249; copy number 8: 484; copy number 9: 85; copy number 10: 1; copy number 11: 35; copy number 12: 580; copy number 13: 19; copy number 14: 3; copy number 15: 23; copy number 16: 43; copy number 17: 62; copy number 18: 41; copy number 26: 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,626 genes in 22 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,419,625–154,628,013, 495 genes, copy number 11–16 (broad region; genes not listed).
- chr2:76,445,079–76,595,678, 2 genes, copy number 7: RN7SKP203, RN7SKP164.
- chr2:77,652,025–78,290,469, 1 gene, copy number 7 (within-gene range 6–7): AC012494.1.
- chr2:78,088,729–78,599,406, 4 genes, copy number 7: AC012494.2, CYCSP6, AC064872.1, AC092660.1.
- chr5:41,730,065–43,707,405, 52 genes, copy number 8: OXCT1, AC034222.2, OXCT1-AS1, AC034222.1, C5orf51, FBXO4, RPSAP38, Y_RNA, MTHFD2P6, AC108099.1, GHR, SERBP1P6, AC093225.1, AC113368.1, CCDC152, SELENOP, AC008945.1, AC008945.2, PPIAP77, PRELID3BP4, PRELID3BP5, PRELID3BP6, PRELID3BP7, AC008875.1, AC025171.1, AC025171.3, AC025171.5, ANXA2R, AC025171.2, AC025171.4, ZNF131, AC106800.3, NIM1K, AC106800.1, AC106800.2, TUBAP14, HMGCS1, AC114947.2, AC114947.1, CCL28, TMEM267, AC114956.2, C5orf34, EEF1A1P19, C5orf34-AS1, AC114956.1, PAIP1, NNT-AS1, AC010435.1, AMD1P3, NNT, RPL29P12.
- chr5:50,396,192–51,665,048, 21 genes, copy number 8–9: EMB, AC112187.2, AC112187.1, AC112187.3, PARP8, AC022441.1, AC022441.3, AC022441.2, AC008808.2, LINC02106, AC008808.1, RNU6-480P, AC091834.1, RNU6-1296P, AC026798.1, AC010478.1, ISL1, HMGB1P47, AC091860.1, AC022433.1, AC091860.2.
- chr8:36,378,069–46,028,892, 176 genes, copy number 7–16 (broad region; genes not listed).
- chr8:49,740,216–58,272,450, 120 genes, copy number 8–12 (broad region; genes not listed).
- chr9:29,254,075–29,318,952, 2 genes, copy number 8: AL162388.1, AL353684.1.
- chr10:10,365,180–21,293,011, 162 genes, copy number 8–18 (within-gene range 5–18) (broad region; genes not listed).
- chr10:29,891,032–31,529,814, 33 genes, copy number 7–8: AL353093.1, JCAD, RNU6-598P, EEF1A1P39, AL353796.1, MTPAP, AL353796.2, DNM1P17, GOLGA2P6, RN7SL241P, MIR7162, NIFKP1, AL161651.1, CCND3P1, MAP3K8, HNRNPA1P32, AL590068.4, AL590068.1, RN7SL63P, AL590068.2, LYZL2, SVIL2P, LINC02644, ZNF438, AL359532.1, DDX10P1, AL359546.1, LINC02664, ZEB1-AS1, RNA5SP309, ZEB1, SPTLC1P1, AL117340.1.
- chr16:29,380,242–29,380,345, 1 gene, copy number 8: AC025279.3.
- chr16:32,475,051–32,478,250, 1 gene, copy number 26: ABCD1P3.
- chr16:33,808,778–33,810,767, 1 gene, copy number 10: AC136428.3.
- chr18:20,946,906–27,190,698, 124 genes, copy number 7–8 (broad region; genes not listed).
- chr18:27,932,879–28,177,946, 3 genes, copy number 11: CDH2, AC110015.1, AC006249.1.
- chr18:31,318,160–32,470,882, 40 genes, copy number 17: DSG1, DSG1-AS1, RNU6-167P, DSG4, Y_RNA, DSG3, AC021549.1, DSG2, DSG2-AS1, TTR, B4GALT6, AC017100.1, RN7SKP44, LRRC37A7P, AC017100.2, SLC25A52, TRAPPC8, AC022960.1, AC022960.3, AC022960.2, RNU6-1050P, AC009831.1, PGDP1, AC009831.2, AC009831.4, RNF125, AC011825.3, AC009831.3, AC011825.1, AC011825.4, RNF138, AC011825.2, GAREM1, RNA5SP453, MEP1B, CLUHP6, AC015563.1, Y_RNA, AC015563.2, HNRNPA1P7.
- chr18:32,511,663–32,582,828, 2 genes, copy number 17: WBP11P1, AC025887.1.
- chr18:48,475,487–49,470,223, 21 genes, copy number 12: RNA5SP456, AC024288.1, POLR3GP2, CTIF, AC048380.2, AC048380.3, MIR4743, AC048380.1, AC022919.1, AC093567.1, SMAD7, AC114684.1, AC016866.3, AC016866.1, DYM, MIR4744, AC016866.2, AC044840.1, AC100778.1, AC100778.4, PRR13P4.
- chr19:24,004,358–24,163,425, 7 genes, copy number 7: RNA5-8SP4, AC092279.1, ZNF254, AC092279.2, BNIP3P40, AC073534.2, AC073534.1.
- chr20:31,341,371–35,753,719, 173 genes, copy number 7 (broad region; genes not listed).
- chr21:7,744,962–18,967,058, 185 genes, copy number 8–14 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,844. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
